Gene-level copy-number profile of tumor specimen ALCH-B2YJ-TTP1-A from ALCHEMIST case ALCH-B2YJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.0 years (29,571 days).
Specimen ALCH-B2YJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8dc3d64f-f7de-46fa-99c3-43faab4434f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2YJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/2a477e4b-a046-4e8e-aaf6-d0229c52d352

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 2,920; copy number 2: 29,092; copy number 3: 20,713; copy number 4: 3,997; copy number 5: 1,302; copy number 6: 230; copy number 7: 5; copy number 8: 7; copy number 9: 52.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,003,592–132,013,199, 2 genes (within-gene range 0–2): ACSL6-AS1, AC034228.1.
- chr6:35,070,871–35,071,049, 1 gene (within-gene range 0–3): AL138721.1.
- chr6:158,764,661–158,764,753, 1 gene (within-gene range 0–2): MIR3918.
- chr9:60,914,407–61,627,683, 14 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr11:117,178,736–117,207,464, 2 genes (within-gene range 0–2): SIDT2, TAGLN.
- chr11:117,204,967–117,210,292, 1 gene (within-gene range 0–2): AP000892.4.
- chr12:117,889,454–117,891,008, 1 gene (within-gene range 0–2): AC084291.1.
- chr14:101,628,984–101,632,530, 1 gene: AL049836.1.
- chr15:25,185,631–25,243,695, 32 genes (within-gene range 0–2): SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr15:34,415,450–34,490,571, 2 genes (within-gene range 0–2): AC025678.3, HNRNPLP2.
- chr16:33,687,025–33,707,213, 1 gene: BMS1P8.
- chr19:13,874,699–13,906,452, 3 genes (within-gene range 0–2): MIR181C, MIR181D, C19orf57.
- chr19:41,350,853–41,425,001, 1 gene (within-gene range 0–2): AC011462.1.
- chr19:41,386,374–41,425,002, 3 genes: EXOSC5, BCKDHA, AC011462.3.
- chr22:18,605,355–18,719,341, 8 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,596 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,646,230–150,913,292, 12 genes, copy number 6: GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr2:20,246,326–20,352,234, 2 genes, copy number 5: RNU7-113P, PUM2.
- chr3:112,736,447–113,287,459, 13 genes, copy number 6 (within-gene range 4–6): LINC02042, CD200R1L-AS1, CD200R1L, CD200R1, AC074044.1, GTPBP8, NEPRO, AC078785.1, AC078785.3, AC078785.2, LINC02044, BOC, AC026329.1.
- chr4:52,252,820–54,295,272, 36 genes, copy number 5 (within-gene range 4–5): AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2.
- chr4:54,603,211–54,740,715, 2 genes, copy number 5: LINC02260, KIT.
- chr7:95,545,191–95,615,132, 2 genes, copy number 5: AC002451.1, PDK4.
- chr7:155,611,231–155,645,205, 1 gene, copy number 5 (within-gene range 3–5): AC009403.1.
- chr8:51,810,110–144,902,168, 1,409 genes, copy number 5–6 (broad region; genes not listed).
- chr8:144,973,589–145,066,685, 7 genes, copy number 5: ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:101,451,564–104,164,379, 57 genes, copy number 7–9: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.
- chr12:25,882,955–27,425,289, 30 genes, copy number 5 (within-gene range 3–5): AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:92,794,305–92,839,947, 1 gene, copy number 5: GOLGA5.
- chr16:1,333,638–1,364,113, 4 genes, copy number 6 (within-gene range 3–6): BAIAP3, TSR3, GNPTG, AL031709.1.
- chr16:88,803,789–88,811,937, 2 genes, copy number 5: CDT1, APRT.
- chr17:75,318,076–75,406,162, 6 genes, copy number 6: GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678.
- chr21:40,863,994–41,357,727, 7 genes, copy number 8: YRDCP3, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B.
- chr22:23,462,086–23,486,980, 1 gene, copy number 5: FAM230I.

Autosomal genes at a single copy (total copy number 1): 2,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
